Somatic mutation profile of tumor specimen 0DQZ4E from CCDI case PBCFPD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 4.4 years (1,601 days).
Specimen 0DQZ4E: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26ccdf08-6433-4c34-926d-9baa4f6dc85e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQZ3H (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d6014c7-ebac-447e-8412-7e8cc2d55cf2

The open-access MAF lists 24 somatic variants for this specimen: 18 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 18, Silent 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACTIN | c.2170G>A p.V724I | Missense Mutation (SNP) | VAF 17/262 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50266607; called by muse, mutect2
- CXCR2 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 281/615 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); catalogued as rs776644645, COSV59280997; called by muse, mutect2, varscan2
- DNAI1 | c.1988G>A p.R663H | Missense Mutation (SNP) | VAF 46/516 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs150107677; called by muse, mutect2
- LATS2 | c.802G>A p.G268R | Missense Mutation (SNP) | VAF 12/270 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.593); catalogued as rs945250367; called by muse, mutect2
- MASP1 | c.1978T>A p.W660R | Missense Mutation (SNP) | VAF 132/184 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100536958; called by muse, mutect2, varscan2
- NR0B1 | c.907C>T p.R303C | Missense Mutation (SNP) | VAF 13/177 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.91); catalogued as rs752190696; called by muse, mutect2
- OSCAR | c.434G>A p.G145D | Missense Mutation (SNP) | VAF 74/191 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.113); catalogued as rs1272626886; called by muse, mutect2, varscan2
- ALKBH8 | c.680A>G p.N227S | Missense Mutation (SNP) | VAF 80/250 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ATXN7L2 | c.2051C>G p.A684G | Missense Mutation (SNP) | VAF 33/416 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.049); called by muse, mutect2
- CEP290 | c.2587A>C p.N863H | Missense Mutation (SNP) | VAF 11/310 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.055); called by muse, mutect2
- CROCC2 | c.4888C>A p.Q1630K | Missense Mutation (SNP) | VAF 15/359 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.232); called by muse, mutect2
- DNAH7 | c.2356G>T p.G786W | Missense Mutation (SNP) | VAF 19/425 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- IBTK | c.3284C>T p.P1095L | Missense Mutation (SNP) | VAF 14/386 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2
- IDUA | c.1625C>T p.A542V | Missense Mutation (SNP) | VAF 17/374 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.175); called by muse, mutect2
- NPS | c.179C>G p.P60R | Missense Mutation (SNP) | VAF 16/378 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- PROKR2 | c.542C>G p.S181C | Missense Mutation (SNP) | VAF 46/606 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2
- TMEM215 | c.94A>C p.M32L | Missense Mutation (SNP) | VAF 163/384 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ZFP28 | c.444G>T p.K148N | Missense Mutation (SNP) | VAF 26/432 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); called by muse, mutect2
- ITGB4 | c.852C>T p.N284= | Silent (SNP) | VAF 183/483 reads (38%) | catalogued as rs529755730, COSV52330572; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN11A | c.138A>G p.E46= | Silent (SNP) | VAF 161/355 reads (45%) | catalogued as rs756961020; called by muse, mutect2, varscan2
- SETD2 | c.2835C>T p.S945= | Silent (SNP) | VAF 18/478 reads (4%) | called by muse, mutect2
- TEKT1 | c.1176G>A p.Q392= | Silent (SNP) | VAF 144/319 reads (45%) | called by muse, mutect2, varscan2
- TMC5 | c.2052C>T p.Y684= (on ENST00000396229 / NM_001105248.1; = p.Y438= on NM_024780.5) | Silent (SNP) | VAF 30/328 reads (9%) | catalogued as rs148418720; called by muse, mutect2
- ZDBF2 | c.537C>T p.R179= | Silent (SNP) | VAF 113/394 reads (29%) | catalogued as rs776102608; called by muse, mutect2
